Somatic mutation profile of tumor specimen HCM-CSHL-0078-C25-06A (aliquot HCM-CSHL-0078-C25-06A-11D-A78M-36) from HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5af6d7e2-69d5-455e-a263-5e9aa2ac1cae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0078-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0078-C25-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca1344a2-271c-4e86-9d9f-898cbdc1745d

The open-access MAF lists 143 somatic variants for this specimen: 97 protein-altering or splice-affecting, 29 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 29, Nonsense Mutation 5, RNA 4, Frame Shift Del 4, 5'Flank 3, Intron 3, 3'Flank 3, 5'UTR 2, 3'UTR 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TAT | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 38/506 reads (8%) | catalogued as rs118203914, CM920661, COSV63532532; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 277/409 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.411T>G p.F137L | Missense Mutation (SNP) | VAF 47/568 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs559187706; called by muse, mutect2
- ADNP | c.3062G>C p.G1021A | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs1237911024; called by muse, mutect2, varscan2
- BCAS3 | c.1969G>A p.V657I (on ENST00000390652 / NM_001353144.2; = p.V642I on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.093); catalogued as rs766648044; called by muse, mutect2, varscan2
- C2orf50 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV101059477; called by muse, mutect2, varscan2
- CADM2 | c.242G>A p.R81H (on ENST00000407528 / NM_001167674.2; = p.R83H on NM_153184.4) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs778733322, CM145841, COSV67385719, COSV67414308; called by muse, mutect2, varscan2
- CDC5L | c.2332C>G p.Q778E | Missense Mutation (SNP) | VAF 109/216 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs756396867; called by muse, mutect2, varscan2
- DOK2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 90/403 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs766198984; called by muse, mutect2, varscan2
- ERBB4 | c.2046G>C p.K682N | Missense Mutation (SNP) | VAF 39/436 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53593480; called by muse, mutect2
- FAT2 | c.1206G>C p.E402D | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55815910; called by muse, mutect2, varscan2
- FBXO15 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs202075662, COSV99077190; called by muse, mutect2, varscan2
- GABRD | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as rs1259972227; called by muse, mutect2, varscan2
- GRIA2 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); catalogued as COSV52394837, COSV52401238; called by muse, mutect2, varscan2
- HJV | c.1240C>T p.L414F (on ENST00000336751 / NM_213653.4; = p.L301F on NM_145277.5) | Missense Mutation (SNP) | VAF 29/1120 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1553769357; called by muse, mutect2
- HOXD12 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1216506512, COSV101184276; called by muse, mutect2, varscan2
- HRNR | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 122/1146 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769962080, COSV64256820; called by muse, mutect2, varscan2
- LAMA5 | c.778C>A p.R260S | Missense Mutation (SNP) | VAF 223/575 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53362723; called by muse, mutect2, varscan2
- LAMC2 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 112/315 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV51456248; called by muse, mutect2, varscan2
- LPA | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 146/546 reads (27%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.98); catalogued as rs1170862921, COSV60303792; called by muse, mutect2, varscan2
- MINDY4 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs370104814; called by muse, mutect2, varscan2
- MTOR | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as rs376836258, COSV63869206; called by muse, mutect2, varscan2
- NACC2 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.493); catalogued as COSV99508563; called by muse, mutect2
- OR4M1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100270969, COSV60060509; called by mutect2, varscan2
- OXNAD1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1389018393, COSV53265982; called by muse, mutect2, varscan2
- PALM | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs372771354; called by muse, mutect2, varscan2
- POLR1E | c.1046G>A p.R349Q (on ENST00000377792 / NM_001282766.1; = p.R287Q on NM_022490.4) | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as rs745330508, COSV66773064; called by muse, mutect2, varscan2
- PRAMEF27 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 145/550 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174375626; called by muse, mutect2, varscan2
- RGS3 | c.3392C>T p.A1131V (on ENST00000350696 / NM_001282923.2; = p.A850V on NM_130795.4) | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs144334750; called by muse, mutect2, varscan2
- SDE2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs376243963; called by muse, mutect2
- SPN | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs968049985, COSV64070098; called by muse, mutect2, varscan2
- SSTR4 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs372339309; called by muse, mutect2, varscan2
- TAL1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs759386045; called by muse, mutect2, varscan2
- TMEM91 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as rs1032654429, COSV99652565; called by muse, mutect2, varscan2
- TPO | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1396786379, COSV61095304; called by muse, mutect2, varscan2
- TRIP12 | c.3807G>C p.Q1269H | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.948); catalogued as rs745404222; called by muse, mutect2
- USP6NL | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs781289702, COSV53209782; called by muse, mutect2, varscan2
- VEPH1 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 139/259 reads (54%) | catalogued as COSV62882192; called by muse, mutect2, varscan2
- VSTM2A | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs199714481, COSV56493317; called by muse, mutect2, varscan2
- ZFHX4 | c.6683C>T p.S2228F | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99256741; called by muse, mutect2, varscan2
- ZHX3 | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV58388713; called by muse, mutect2
- ZNF516 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1296532817; called by muse, mutect2, varscan2
- ZNF536 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 131/237 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180623012, COSV62818669; called by muse, mutect2, varscan2
- ADGRL3 | c.4396A>G p.S1466G (on ENST00000506720 / NM_001322402.2; = p.S1355G on NM_015236.6) | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ARFGEF3 | c.2435G>C p.S812T | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.6472G>A p.A2158T | Missense Mutation (SNP) | VAF 249/454 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CEACAM18 | c.968G>C p.C323S | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG3 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DDX31 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNASE1L1 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 117/180 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DNASE2 | c.141_142del p.G48Afs*49 | Frame Shift Del (DEL) | VAF 64/410 reads (16%) | called by pindel, varscan2
- FAM169A | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FLG | c.1599G>T p.E533D | Missense Mutation (SNP) | VAF 123/1125 reads (11%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FOXC1 | c.18dup p.V7Rfs*76 | Frame Shift Ins (INS) | VAF 33/64 reads (52%) | called by mutect2, pindel, varscan2
- GAL3ST1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 161/227 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRIA1 | c.2490C>A p.Y830* | Nonsense Mutation (SNP) | VAF 26/250 reads (10%) | called by muse, varscan2
- H4C2 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2
- HAT1 | c.676A>G p.N226D | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.307); called by muse, mutect2
- HECA | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IPO5 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM5C | c.1503_1519del p.W501Cfs*10 | Frame Shift Del (DEL) | VAF 80/131 reads (61%) | called by mutect2, pindel, varscan2
- L3MBTL4 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LPIN2 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 30/449 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MROH5 | c.2816G>C p.S939T | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.466); called by muse, mutect2
- MUC6 | c.6589_6590del p.L2197Ffs*12 | Frame Shift Del (DEL) | VAF 40/166 reads (24%) | called by pindel, varscan2
- NEB | c.16955A>G p.Y5652C | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEUROD6 | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- NLRP4 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- OR51C1P | c.830C>G p.A277G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OTOG | c.7977G>T p.E2659D | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PDE6B | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PHF12 | c.1885C>G p.P629A | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PLXNB2 | c.1679C>G p.S560W | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.785); called by muse, mutect2
- PPHLN1 | c.1254G>C p.Q418H | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PTPN13 | c.7224C>A p.C2408* (on ENST00000411767 / NM_080683.3; = p.C2389* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 68/204 reads (33%) | called by muse, mutect2, varscan2
- RABGAP1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.97); called by muse, mutect2
- RBM26 | c.1303C>G p.P435A | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIOK2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SAMD8 | c.204A>T p.L68F | Missense Mutation (SNP) | VAF 78/133 reads (59%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SCN2A | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 83/589 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SH2B3 | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC5A8 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 42/66 reads (64%) | called by pindel, varscan2
- SLC6A5 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 69/347 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, mutect2
- SLCO1B1 | c.92T>C p.L31S | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TANC1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 167/319 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TLN1 | c.4240G>C p.A1414P | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TMEM121 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMEM237 | c.874G>T p.D292Y (on ENST00000409883 / NM_001044385.3; = p.D284Y on NM_152388.4) | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNKS | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTN | c.31510C>G p.P10504A (on ENST00000591111; = p.P9577A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/191 reads (19%) | PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- WDR62 | c.77del p.P26Rfs*51 | Frame Shift Del (DEL) | VAF 55/264 reads (21%) | called by mutect2, pindel, varscan2
- WNK2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 297/593 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX2 | c.6059G>C p.S2020T | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX2 | c.4558C>T p.R1520* | Nonsense Mutation (SNP) | VAF 38/461 reads (8%) | called by muse, mutect2
- ZNF202 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ZNF423 | c.3835C>G p.Q1279E (on ENST00000563137 / NM_001379286.1; = p.Q1271E on NM_015069.4) | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ZNF551 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1377C>T p.P459= | Silent (SNP) | VAF 115/2248 reads (5%) | catalogued as rs779949072, COSV55000365; called by muse, mutect2
- ATG4B | c.222C>T p.C74= | Silent (SNP) | VAF 74/415 reads (18%) | called by muse, mutect2, varscan2
- C1QTNF8 | c.414C>T p.F138= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- CLSTN2 | c.696G>T p.L232= | Silent (SNP) | VAF 119/242 reads (49%) | called by muse, mutect2, varscan2
- CYP26B1 | c.1131G>A p.Q377= | Silent (SNP) | VAF 64/630 reads (10%) | called by muse, mutect2
- DPF2 | c.432C>T p.G144= | Silent (SNP) | VAF 48/143 reads (34%) | catalogued as COSV52888870; called by muse, mutect2, varscan2
- ELOA2 | c.1182G>A p.K394= | Silent (SNP) | VAF 89/323 reads (28%) | called by muse, mutect2, varscan2
- EVC2 | c.3615C>T p.S1205= | Silent (SNP) | VAF 128/431 reads (30%) | called by muse, mutect2, varscan2
- FLG | c.7242C>T p.F2414= | Silent (SNP) | VAF 139/1211 reads (11%) | called by muse, mutect2, varscan2
- GNAT1 | c.435C>T p.N145= | Silent (SNP) | VAF 24/368 reads (7%) | catalogued as rs749785058; called by muse, mutect2
- IRX3 | c.1473C>T p.A491= | Silent (SNP) | VAF 125/285 reads (44%) | called by muse, mutect2, varscan2
- KRT37 | c.807G>T p.L269= | Silent (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- MED23 | c.1296C>A p.L432= | Silent (SNP) | VAF 76/348 reads (22%) | called by muse, mutect2, varscan2
- MTNR1B | c.312C>T p.D104= | Silent (SNP) | VAF 26/263 reads (10%) | catalogued as rs139515067; called by muse, mutect2
- NEB | c.10305G>A p.P3435= | Silent (SNP) | VAF 81/513 reads (16%) | catalogued as rs528974814, COSV99415147; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXMIF | c.1749C>T p.P583= | Silent (SNP) | VAF 56/81 reads (69%) | called by muse, mutect2, varscan2
- NF1 | c.8109G>A p.L2703= (on ENST00000358273 / NM_001042492.3; = p.L2682= on NM_000267.3) | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as rs1397862679; called by muse, mutect2, varscan2
- NPC1L1 | c.927C>T p.P309= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs1017546573, COSV56922987; called by muse, mutect2, varscan2
- OBSCN | c.5016G>A p.V1672= | Silent (SNP) | VAF 129/361 reads (36%) | catalogued as COSV99486630; called by muse, mutect2, varscan2
- PGM5 | c.1566C>T p.Y522= | Silent (SNP) | VAF 61/250 reads (24%) | catalogued as rs782534536, COSV67166795; called by muse, mutect2, varscan2
- PIEZO1 | c.4098G>A p.Q1366= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1168119514; called by muse, mutect2, varscan2
- RBM25 | c.462G>A p.E154= | Silent (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- SLC26A8 | c.1770T>C p.I590= | Silent (SNP) | VAF 14/260 reads (5%) | catalogued as rs202135271, COSV62885368; called by muse, mutect2
- SPATA31E1 | c.1080C>T p.D360= | Silent (SNP) | VAF 82/400 reads (21%) | catalogued as rs199568188, COSV57789870; called by muse, mutect2, varscan2
- TIE1 | c.2826T>C p.A942= | Silent (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- TNRC18 | c.5952G>A p.A1984= | Silent (SNP) | VAF 80/349 reads (23%) | catalogued as rs778246311; called by muse, mutect2, varscan2
- TSPAN5 | c.606T>C p.Y202= | Silent (SNP) | VAF 58/191 reads (30%) | catalogued as rs760214816; called by muse, mutect2, varscan2
- VPS13D | c.4890G>A p.Q1630= | Silent (SNP) | VAF 61/155 reads (39%) | called by muse, mutect2, varscan2
- ZNF556 | c.15C>A p.V5= | Silent (SNP) | VAF 43/197 reads (22%) | called by muse, mutect2, varscan2
- AC006305.1 | n.825A>G | RNA (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- ACBD4 | chr17:45143641 G>A | 3'Flank (SNP) | VAF 17/54 reads (31%) | called by muse, varscan2
- C8orf87 | n.87C>T | RNA (SNP) | VAF 26/320 reads (8%) | catalogued as rs771548195; called by muse, mutect2
- DSTN | c.-84G>T | 5'UTR (SNP) | VAF 54/259 reads (21%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+325T>C | Intron (SNP) | VAF 122/502 reads (24%) | called by muse, mutect2, varscan2
- FAM161A | c.*1279T>C | 3'UTR (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- GPNMB | c.541+30C>A | Intron (SNP) | VAF 119/290 reads (41%) | called by muse, mutect2, varscan2
- HADH | chr4:107989882 C>G | 5'Flank (SNP) | VAF 38/228 reads (17%) | catalogued as rs536959577, COSV100531279, COSV58848862; called by muse, mutect2, varscan2
- HAUS7 | chrX:153470957 T>A | 5'Flank (SNP) | VAF 60/97 reads (62%) | called by muse, mutect2, varscan2
- LINC00602 | n.592C>A | RNA (SNP) | VAF 123/371 reads (33%) | catalogued as rs969920362; called by muse, mutect2, varscan2
- LINC01193 | n.1330C>A | RNA (SNP) | VAF 41/406 reads (10%) | called by muse, mutect2, varscan2
- PADI4 | c.-2C>T | 5'UTR (SNP) | VAF 67/153 reads (44%) | catalogued as rs200461292; called by muse, mutect2, varscan2
- PYCARD | c.275-76del | Intron (DEL) | VAF 36/159 reads (23%) | called by mutect2, pindel, varscan2
- RN7SL484P | chr15:99791492 G>C | 3'Flank (SNP) | VAF 28/286 reads (10%) | called by muse, mutect2
- RNU7-174P | chr8:80559425 C>T | 5'Flank (SNP) | VAF 168/633 reads (27%) | catalogued as rs1159050845; called by muse, mutect2, varscan2
- VMP1 | c.*1440C>A | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- WASHC3 | chr12:102011836 G>A | 3'Flank (SNP) | VAF 14/185 reads (8%) | catalogued as rs1212203202; called by muse, mutect2
